Somatic mutation profile of tumor specimen 6838157f-361d-4e95-b933-35bd46 (aliquot 6838157f-361d-4e95-b933-35bd46_D6) from CPTAC case 05BR005, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 50.0 years (18,249 days).
Specimen 6838157f-361d-4e95-b933-35bd46: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 637d9724-fd83-4535-809b-18021ee6e1ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen e7e44e0d-7412-4d26-814b-ff0d45 (Blood Derived Normal), aliquot e7e44e0d-7412-4d26-814b-ff0d45_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/999e0850-eb45-4d3f-9c3e-3d6fea8000ce

The open-access MAF lists 32 somatic variants for this specimen: 24 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 4, RNA 2, 3'Flank 1, Frame Shift Del 1, Nonsense Mutation 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRPF3 | c.3554G>A p.R1185H | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756729676; called by muse, mutect2, varscan2
- DCLRE1A | c.1543G>T p.V515F | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.129); catalogued as COSV63748177; called by muse, mutect2
- FRMPD4 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as rs1215910141, COSV66217808; called by muse, mutect2, varscan2
- KIF15 | c.899C>T p.T300I | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as rs1330365018; called by muse, mutect2, varscan2
- MAS1L | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 80/304 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs368893305; called by muse, mutect2, varscan2
- PTPRS | c.4747G>A p.G1583S | Missense Mutation (SNP) | VAF 65/255 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777981018, COSV99508568; called by muse, mutect2, varscan2
- RB1 | c.957A>C p.K319N | Missense Mutation (SNP) | VAF 16/327 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as CX962710; called by muse, mutect2
- SART3 | c.821C>T p.A274V (on ENST00000228284; = p.A256V on NM_014706.4) | Missense Mutation (SNP) | VAF 107/414 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.127); catalogued as rs774883843; called by muse, mutect2, varscan2
- SMPD3 | c.1646-3C>T | Splice Region (SNP) | VAF 62/177 reads (35%) | catalogued as rs756547242; called by mutect2, varscan2
- ZBTB39 | c.1360G>A p.A454T | Missense Mutation (SNP) | VAF 100/341 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs770291969, COSV100268112; called by muse, mutect2, varscan2
- AJM1 | c.34T>C p.S12P | Missense Mutation (SNP) | VAF 10/326 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.112); called by muse, mutect2
- AKAP9 | c.8864A>G p.E2955G (on ENST00000359028; = p.E2931G on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CDH18 | c.2335G>T p.E779* | Nonsense Mutation (SNP) | VAF 66/228 reads (29%) | called by muse, mutect2, varscan2
- DDX59 | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); called by muse, mutect2
- LLGL1 | c.606G>T p.Q202H | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- LRCH2 | c.881A>G p.K294R | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MTG1 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 62/223 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- OR6K3 | c.485C>A p.A162E (on ENST00000368146; = p.A146E on NM_001005327.2) | Missense Mutation (SNP) | VAF 34/468 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); called by muse, mutect2
- PDS5A | c.513_514del p.F172Lfs*6 | Frame Shift Del (DEL) | VAF 26/75 reads (35%) | called by pindel, varscan2
- PDZD4 | c.214A>C p.T72P | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RNF213 | c.10274G>A p.R3425K | Missense Mutation (SNP) | VAF 123/658 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TRIM72 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ZNF534 | c.1264C>A p.R422S (on ENST00000332323 / NM_001143939.3; = p.R409S on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.259); called by muse, mutect2
- ZSCAN1 | c.423G>C p.E141D | Missense Mutation (SNP) | VAF 43/460 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.191); called by muse, mutect2
- ACIN1 | c.3261C>G p.A1087= | Silent (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- B4GALNT1 | c.1035T>C p.S345= | Silent (SNP) | VAF 73/228 reads (32%) | catalogued as rs1300815734; called by muse, mutect2, varscan2
- DNAH10 | c.5691C>T p.T1897= (on ENST00000409039; = p.T1836= on NM_207437.3) | Silent (SNP) | VAF 30/113 reads (27%) | catalogued as rs202158921; called by muse, mutect2, varscan2
- SLC6A17 | c.1878C>T p.V626= | Silent (SNP) | VAF 89/305 reads (29%) | catalogued as rs367697353; called by muse, mutect2, varscan2
- AL669831.6 | chr1:786423 T>C | 3'Flank (SNP) | VAF 98/279 reads (35%) | catalogued as rs1557539405; called by muse, mutect2, varscan2
- GPRC5B | chr16:19885270 G>T | 5'Flank (SNP) | VAF 61/200 reads (31%) | catalogued as rs774789413; called by muse, mutect2, varscan2
- LRRC37A5P | n.350C>T | RNA (SNP) | VAF 52/264 reads (20%) | catalogued as rs551973551; called by muse, mutect2, varscan2
- OR2M1P | n.708A>T | RNA (SNP) | VAF 168/827 reads (20%) | called by muse, mutect2, varscan2
